Gene-level copy-number profile of tumor specimen HCM-SANG-1322-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1322-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1322-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 30e5b09d-ada7-4aae-8107-fccffaeefbf8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1322-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/035ad2b4-ccc7-453d-bf2f-de8f4ac4373a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,984; copy number 2: 27,549; copy number 3: 22,238; copy number 4: 2,439; copy number 5: 373; copy number 6: 41; copy number 7: 16; copy number 8: 114; copy number 9: 72; copy number 10: 27; copy number 12: 29; copy number 17: 9; copy number 21: 10.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,201,647–87,357,882, 5 genes (within-gene range 0–1): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 691 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:40,240,167–44,716,486, 76 genes, copy number 5–9 (broad region; genes not listed).
- chr6:32,148,359–32,763,532, 35 genes, copy number 9–17: PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721, RNF5, MIR6833, AGER, AL662884.1, PBX2, GPSM3, NOTCH4, TSBP1-AS1, TSBP1, HNRNPA1P2, RNU6-603P, BTNL2, HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2.
- chr6:36,740,775–39,725,408, 55 genes, copy number 5–9: CPNE5, Z85996.2, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P.
- chr6:41,636,882–41,654,244, 1 gene, copy number 10: MDFI.
- chr6:41,789,896–41,895,361, 1 gene, copy number 10 (within-gene range 2–10): USP49.
- chr6:41,832,854–46,207,386, 120 genes, copy number 6–21 (broad region; genes not listed).
- chr9:33,383,179–33,818,795, 30 genes, copy number 5 (within-gene range 4–5): AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2.
- chr11:25,588,475–29,064,322, 39 genes, copy number 6–10: RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P.
- chr11:44,095,673–44,978,028, 14 genes, copy number 7: EXT2, ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685.
- chr11:46,123,031–46,386,608, 10 genes, copy number 6–7: AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:118,077,012–118,750,263, 34 genes, copy number 9–12 (within-gene range 2–12): TMPRSS4, SCN4B, SCN2B, JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E, AP001582.1, CD3D, CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2.
- chr15:90,083,045–101,979,093, 276 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
